MMRF case MMRF_1597 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/421aa881-f90f-4ec7-87ee-6707bed4ffe8

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 53 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 54.0 years (19,706 days); ISS stage: III; Days to last known disease status: 1,260 days (3.4 years); Days to last follow up: 1,260 days (3.4 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 1 day.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 2 days; Days to treatment end: 12 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 2 days; Days to treatment end: 16 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 27 days; Days to treatment end: 100 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 27 days; Days to treatment end: 27 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 117 days; Days to treatment end: 117 days.
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 147 days; Days to treatment end: 149 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 150 days; Days to treatment end: 150 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 152 days; Days to treatment end: 152 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 251 days; Days to treatment end: 501 days (1.4 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 502 days (1.4 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 3.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 44.3 mg/dL; Immunoglobulin G 53 g/L; Immunoglobulin A 0.06 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 8.14 µg/mL; Lactate Dehydrogenase 1.72 µkat/L; Hemoglobin 5.21 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 268 ×10⁹/L; Creatinine 132 µmol/L; Blood Urea Nitrogen 7.4 mmol/L; Calcium 3.42 mmol/L; Albumin 41 g/L; Total Protein 10.5 g/dL; Glucose 5.4 mmol/L.
- Day 106 (ECOG 1): M Protein 1.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.29 mg/dL; Beta 2 Microglobulin 2.96 µg/mL; Hemoglobin 7.38 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 235 ×10⁹/L; Creatinine 77 µmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 7.6 g/dL; Glucose 5.5 mmol/L.
- Day 169: M Protein 7 g/dL; Hemoglobin 6.51 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 36 ×10⁹/L; Creatinine 71 µmol/L; Blood Urea Nitrogen 2.5 mmol/L.
- Day 281 (ECOG 0): M Protein 6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.08 mg/dL; Immunoglobulin G 14.1 g/L; Immunoglobulin A 0.52 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 1.93 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 122 ×10⁹/L; Creatinine 81 µmol/L; Blood Urea Nitrogen 4.6 mmol/L; Calcium 2.21 mmol/L; Albumin 38 g/L; Total Protein 7 g/dL; Glucose 5.2 mmol/L.
- Day 336 (ECOG 0): M Protein 4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.01 mg/dL; Immunoglobulin G 11.8 g/L; Immunoglobulin A 0.9 g/L; Immunoglobulin M 0.31 g/L; Lactate Dehydrogenase 1.87 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 131 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 4.5 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 6.9 g/dL; Glucose 6.5 mmol/L.
- Day 440 (ECOG 0): M Protein 3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.46 mg/dL; Lactate Dehydrogenase 2.03 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 124 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 8.7 mmol/L; Calcium 2.37 mmol/L; Albumin 40 g/L; Total Protein 7.1 g/dL; Glucose 6 mmol/L.
- Day 552 (ECOG 0): M Protein 3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.99 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.6 mg/dL; Immunoglobulin G 12.2 g/L; Immunoglobulin A 1.78 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 110 µmol/L; Blood Urea Nitrogen 5.5 mmol/L; Calcium 2.42 mmol/L; Albumin 42 g/L; Total Protein 7.5 g/dL; Glucose 5.9 mmol/L.
- Day 615 (ECOG 0): M Protein 3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.54 mg/dL; Immunoglobulin G 13.1 g/L; Immunoglobulin A 1.48 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 8.1 mmol/L; Calcium 2.35 mmol/L; Albumin 44 g/L; Total Protein 7.8 g/dL; Glucose 5.6 mmol/L.
- Day 729 (ECOG 0): M Protein 4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.95 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.17 mg/dL; Immunoglobulin G 13.2 g/L; Immunoglobulin A 1.38 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 230 ×10⁹/L; Creatinine 107 µmol/L; Blood Urea Nitrogen 7.9 mmol/L; Calcium 2.49 mmol/L; Albumin 44 g/L; Total Protein 7.7 g/dL; Glucose 6 mmol/L.
- Day 812 (ECOG 0): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.85 mg/dL; Immunoglobulin G 12.5 g/L; Immunoglobulin A 1.28 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 2.03 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 226 ×10⁹/L; Creatinine 119 µmol/L; Blood Urea Nitrogen 7.6 mmol/L; Calcium 2.55 mmol/L; Albumin 44 g/L; Total Protein 7.6 g/dL; Glucose 4.9 mmol/L.
- Day 894 (ECOG 0): M Protein 3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.19 mg/dL; Immunoglobulin G 14.2 g/L; Immunoglobulin A 1.51 g/L; Immunoglobulin M 0.31 g/L; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 9.8 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 240 ×10⁹/L; Creatinine 113 µmol/L; Blood Urea Nitrogen 9.2 mmol/L; Calcium 2.68 mmol/L; Albumin 49 g/L; Total Protein 8.5 g/dL; Glucose 4.3 mmol/L.
- Day 985 (ECOG 0): M Protein 3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.45 mg/dL; Immunoglobulin G 14.4 g/L; Immunoglobulin A 1.54 g/L; Immunoglobulin M 0.33 g/L; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 9.73 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 231 ×10⁹/L; Creatinine 109 µmol/L; Blood Urea Nitrogen 6.5 mmol/L; Calcium 2.52 mmol/L; Albumin 47 g/L; Total Protein 8 g/dL; Glucose 6.8 mmol/L.
- Day 1,092 (ECOG 0): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.38 mg/dL; Immunoglobulin G 14.8 g/L; Immunoglobulin A 1.59 g/L; Immunoglobulin M 0.36 g/L; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 9.42 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 254 ×10⁹/L; Creatinine 107 µmol/L; Blood Urea Nitrogen 3.9 mmol/L; Calcium 2.42 mmol/L; Albumin 43 g/L; Total Protein 8.1 g/dL; Glucose 6 mmol/L.
- Day 1,204 (ECOG 0): M Protein 3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.48 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.43 mg/dL; Immunoglobulin G 12.9 g/L; Immunoglobulin A 1.51 g/L; Immunoglobulin M 0.42 g/L; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 9.24 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 227 ×10⁹/L; Creatinine 104 µmol/L; Blood Urea Nitrogen 7.2 mmol/L; Calcium 2.33 mmol/L; Albumin 45 g/L; Total Protein 7.9 g/dL; Glucose 5.7 mmol/L.
- Day 1,260 (ECOG 0): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.4 mg/dL; Immunoglobulin G 14.4 g/L; Immunoglobulin A 1.58 g/L; Immunoglobulin M 0.39 g/L; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 9.61 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 234 ×10⁹/L; Creatinine 107 µmol/L; Blood Urea Nitrogen 6.8 mmol/L; Calcium 2.44 mmol/L; Albumin 46 g/L; Total Protein 8.2 g/dL; Glucose 5.4 mmol/L.

Other clinical attributes
- Day 1: Weight: 88 kg; Height: 169 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Colorectal Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1597_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1597_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
